Gene-level copy-number profile of tumor specimen TCGA-21-1081-01A from TCGA case TCGA-21-1081, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.7 years (25,440 days).
Specimen TCGA-21-1081-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.da18ddfb-a866-40af-90e3-119040c81b72.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-21-1081-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1d16eacb-82a6-464e-9b8c-34d7bbb96a83

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,444; copy number 2: 30,021; copy number 3: 2,991; copy number 4: 11,203; copy number 5: 8,237; copy number 6: 3,044; copy number 7: 1,114; copy number 8: 399; copy number 9: 134; copy number 10: 129; copy number 11: 10; copy number 12: 21; copy number 16: 46; copy number 17: 7; copy number 26: 8; copy number 31: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-21-1081-01A-01D-0685-01): tumor purity 0.49, ploidy 2.93, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:70,638,073–70,920,738, 1 gene (within-gene range 0–2): PTPRR.
- chr12:70,906,917–70,907,018, 1 gene: Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13,124 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:83,924,157–98,169,774, 98 genes, copy number 5–11 (broad region; genes not listed).
- chr3:99,817,837–192,767,764, 1,538 genes, copy number 6–12 (within-gene range 4–12) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6 (broad region; genes not listed).
- chr6:167,607–2,525,976, 38 genes, copy number 5 (within-gene range 4–5): AL035696.2, AL035696.3, AL035696.4, AL035696.1, AL365272.1, DUSP22, IRF4, AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1, AL356130.1, LINC01622, AL033381.2, AL033381.1, AL033381.3, FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1, GMDS, AL035693.1, GMDS-DT, HMGN2P28, AL031768.2, AL031768.1.
- chr6:3,585,101–32,224,067, 851 genes, copy number 5–8 (broad region; genes not listed).
- chr6:36,940,071–37,555,422, 20 genes, copy number 7: AL122034.1, PI16, MTCH1, FGD2, COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462.
- chr6:49,077,712–51,410,537, 34 genes, copy number 6: AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL132799.1, AL360175.1, AL135908.1, TFAP2D, TFAP2B, RPS17P5, AL049693.1, FTH1P5, AL158050.2, AL158050.1.
- chr7:70,972–119,179,149, 2,160 genes, copy number 5–6 (broad region; genes not listed).
- chr8:38,269,704–38,382,272, 1 gene, copy number 10 (within-gene range 2–10): NSD3.
- chr8:38,335,981–145,066,685, 1,661 genes, copy number 5–10 (broad region; genes not listed).
- chr13:30,151,886–31,437,999, 33 genes, copy number 5: LINC00384, LINC00385, AL157770.1, KATNAL1, RNU6-64P, PRDX2P1, LINC00427, LINC00426, AL356750.1, AL161893.1, LINC01058, UBE2L5, HMGB1, AL353648.1, RBM22P2, MFAP1P1, PTPN2P2, USPL1, Metazoa_SRP, ALOX5AP, LINC00398, LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066, AL158065.1, WDR95P, HSPH1, B3GLCT, ANKRD26P4, AL161616.2.
- chr13:37,009,312–95,301,475, 702 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr13:109,101,261–110,129,136, 17 genes, copy number 17–31 (within-gene range 3–31): MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P.
- chr13:110,809,676–110,990,579, 8 genes, copy number 26: LINC00567, PRECSIT, ANKRD10, ANKRD10-IT1, AL442128.2, PARP1P1, AL442128.1, LINC00431.
- chr13:112,647,044–113,974,076, 46 genes, copy number 16: ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, C13orf46.
- chr14:99,397,748–103,110,559, 210 genes, copy number 6 (broad region; genes not listed).
- chr16:11,555–35,912,516, 1,419 genes, copy number 5 (broad region; genes not listed).
- chr19:22,391,019–22,532,485, 1 gene, copy number 5 (within-gene range 2–5): ZNF98.
- chr19:22,455,988–58,605,223, 1,766 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–26,251,546, 540 genes, copy number 6 (broad region; genes not listed).
- chr21:10,328,411–46,665,124, 745 genes, copy number 5 (broad region; genes not listed).
- chr22:15,290,718–18,131,138, 115 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr22:20,652,730–28,679,865, 411 genes, copy number 6–9 (within-gene range 2–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 81. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
